Gene-level copy-number profile of specimen HCM-SANG-0299-C15-85A from HCMI case HCM-SANG-0299-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0299-C15-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 31748bf5-81fd-4eb9-9301-7a5044a05822.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0299-C15-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,714 have no estimate.
https://portal.gdc.cancer.gov/files/11a496be-5529-448a-816d-42aaf987c316

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 517; copy number 1: 635; copy number 2: 24,547; copy number 3: 19,761; copy number 4: 12,808; copy number 5: 294; copy number 6: 155; copy number 7: 37; copy number 10: 9; copy number 13: 65; copy number 19: 8; copy number 22: 2; copy number 26: 3; copy number 34: 3; copy number 106: 17; copy number 119: 21; copy number 121: 19; copy number 124: 2; copy number 134: 5; copy number 138: 1.

Homozygous deletions (total copy number 0; autosomes only): 6 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:245,673,732–245,676,478, 1 gene (within-gene range 0–4): AC104462.1.
- chr13:18,467,172–18,611,675, 5 genes: ZNF962P, BNIP3P7, LINC00349, LONRF2P2, LINC00388.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 641 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,791,397–12,898,270, 8 genes, copy number 7: PRAMEF1, LINC01784, PRAMEF11, PRAMEF30P, HNRNPCL1, PRAMEF2, PRAMEF4, PRAMEF10.
- chr1:145,281,116–145,739,288, 13 genes, copy number 5 (within-gene range 4–5): RNVU1-14, AC245014.3, AC245014.1, NBPF20, PFN1P3, RNU1-154P, RNVU1-31, AC239860.2, AC239860.1, NBPF25P, GPR89A, PDZK1, CD160.
- chr1:145,926,590–146,914,294, 24 genes, copy number 5 (within-gene range 4–5): LIX1L-AS1, AC243547.3, LIX1L, ANKRD34A, AC243547.2, POLR3GL, TXNIP, HJV, AC239799.2, RNVU1-6, LINC01719, NBPF10, NOTCH2NLA, AC239799.1, RNU6-1071P, NUDT4P2, SEC22B4P, PPIAL4H, RNVU1-29, RNVU1-25, AC245407.1, HYDIN2, RNA5SP536, AC241929.1.
- chr1:148,271,884–148,750,099, 25 genes, copy number 5–6: LINC01731, AC245100.3, LINC01138, LINC02806, AC245100.1, AC245100.5, Y_RNA, MIR5087, RNVU1-21, AC245100.6, RNVU1-1, RNU1-155P, MIR6077, RNVU1-2, AC245100.4, RNVU1-3, AC245100.2, AC245100.8, AC245100.7, PPIAL4G, RNVU1-27, NBPF14, NOTCH2NLB, RNU6-1171P, NUDT4B.
- chr1:148,808,181–149,048,286, 1 gene, copy number 5 (within-gene range 2–5): PDE4DIP.
- chr1:148,939,739–149,162,944, 7 genes, copy number 5: RNU2-38P, AC239802.1, AC239802.2, AC239804.1, NBPF9, AC239804.2, RNVU1-24.
- chr1:211,382,736–211,435,570, 2 genes, copy number 5: LINC00467, SNX25P1.
- chr1:211,571,568–211,583,725, 2 genes, copy number 5: SLC30A1, AC105275.2.
- chr1:212,824,027–212,824,505, 1 gene, copy number 5: AC104333.3.
- chr1:223,863,726–223,950,416, 2 genes, copy number 5: ACTBP11, CICP5.
- chr1:223,976,146–223,976,249, 1 gene, copy number 5: RNU6-1319P.
- chr1:224,208,741–224,213,625, 1 gene, copy number 5: AC092809.2.
- chr1:228,555,793–228,687,826, 23 genes, copy number 5: RNA5SP19, RNA5SP162, RNA5S1, RNA5S2, RNA5S3, RNA5S4, RNA5S5, RNA5S6, RNA5S7, RNA5S8, RNA5S9, RNA5S10, RNA5S11, RNA5S12, RNA5S13, RNA5S14, RNA5S15, RNA5S16, RNA5S17, RNA5SP18, DUSP5P1, AL713899.1, FTH1P2.
- chr1:229,256,892–229,305,894, 2 genes, copy number 5 (within-gene range 4–5): AL162595.1, RAB4A.
- chr1:232,160,091–232,223,145, 4 genes, copy number 5: AL353052.1, AL353052.2, BX323014.1, RN7SL299P.
- chr1:246,690,047–246,768,137, 3 genes, copy number 5: AL591848.1, SCCPDH, RPL35AP6.
- chr5:32,522,758–42,191,523, 148 genes, copy number 6 (broad region; genes not listed).
- chr8:86,553,977–86,743,675, 1 gene, copy number 5 (within-gene range 4–5): CNGB3.
- chr8:86,657,388–88,887,573, 17 genes, copy number 5 (within-gene range 4–5): GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1.
- chr8:90,058,608–90,687,863, 3 genes, copy number 5 (within-gene range 3–5): CALB1, AC004083.1, LINC00534.
- chr8:101,166,805–103,501,895, 68 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr8:125,648,327–129,683,770, 48 genes, copy number 119–138 (within-gene range 3–138): AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2, KNOP1P5, AC024681.1, RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2, PCAT1, AC083923.1, RNU11-4P, AC024382.1, CASC19, PRNCR1, AC020688.1, CASC8, AC018714.1, POU5F1B, CCAT2, AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686.
- chr9:64,621,560–64,709,311, 3 genes, copy number 5: AQP7P2, AL445665.1, BMS1P11.
- chr12:22,609,228–28,978,685, 107 genes, copy number 10–106 (within-gene range 2–106) (broad region; genes not listed).
- chr12:37,575,587–46,972,155, 122 genes, copy number 5 (broad region; genes not listed).
- chr18:45,034–94,330, 5 genes, copy number 5–6: AP001005.1, TUBB8B, AP001005.3, IL9RP4, AP001005.2.

Autosomal genes at a single copy (total copy number 1): 562. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
